Somatic mutation profile of tumor specimen TCGA-10-0930-01A (aliquot TCGA-10-0930-01A-02W-0420-08) from TCGA case TCGA-10-0930, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 70.5 years (25,737 days).
Specimen TCGA-10-0930-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3fb7d366-4059-4d98-bb4c-c339398919ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-10-0930-11A (Solid Tissue Normal), aliquot TCGA-10-0930-11A-01W-0420-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8183cb50-383b-4858-9b81-1e1e3f527b66

The open-access MAF lists 164 somatic variants for this specimen: 132 protein-altering or splice-affecting, 29 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 29, Splice Site 9, Nonsense Mutation 7, Frame Shift Del 6, In Frame Del 4, Nonstop Mutation 2, Frame Shift Ins 2, Intron 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL6A3 | c.5838+1G>T p.X1946_splice | Splice Site (SNP) | VAF 34/56 reads (61%) | catalogued as rs1559234260, COSV55099345; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACACB | c.3383C>G p.T1128R | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.351); catalogued as COSV58140547; called by muse, mutect2, varscan2
- ADAMTS16 | c.1978T>A p.F660I | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99940307; called by muse, mutect2
- ALPK2 | c.2023G>C p.E675Q | Missense Mutation (SNP) | VAF 54/603 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.197); catalogued as COSV64494891; called by muse, mutect2
- APCDD1L | c.148A>G p.I50V | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV64487231; called by muse, mutect2
- ARID1A | c.1991C>G p.S664* | Nonsense Mutation (SNP) | VAF 232/354 reads (66%) | catalogued as COSV100250329, COSV61383603; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.704C>G p.S235C | Missense Mutation (SNP) | VAF 65/243 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs1164265674, COSV63438510; called by muse, mutect2, varscan2
- ATN1 | c.3212C>T p.A1071V | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.731); catalogued as COSV57547240; called by muse, mutect2, varscan2
- BRI3BP | c.244C>A p.L82M | Missense Mutation (SNP) | VAF 509/1121 reads (45%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.471); catalogued as COSV58296765; called by muse, mutect2, varscan2
- BRWD1 | c.1185G>T p.W395C | Missense Mutation (SNP) | VAF 170/258 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60899855; called by muse, mutect2, varscan2
- BTBD1 | c.520C>G p.H174D | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV55603889, COSV55604236; called by muse, mutect2, varscan2
- BUB1B | c.2460T>A p.D820E | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.055); catalogued as COSV99806633; called by muse, mutect2, varscan2
- CACNA1D | c.2080G>A p.A694T (on ENST00000350061 / NM_001128840.3; = p.A714T on NM_000720.4) | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV55456669; called by muse, mutect2, varscan2
- CAGE1 | c.1303G>T p.V435L (on ENST00000512086; = p.V299L on NM_205864.3) | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV57079368; called by muse, mutect2, varscan2
- CALHM1 | c.344T>G p.V115G | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV61707963; called by muse, mutect2, varscan2
- CCDC80 | c.1966A>C p.K656Q | Missense Mutation (SNP) | VAF 94/437 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV52818623; called by muse, mutect2, varscan2
- CCR8 | c.696C>G p.N232K | Missense Mutation (SNP) | VAF 50/255 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as COSV58337634; called by muse, mutect2, varscan2
- CDH19 | c.1523A>T p.N508I | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV50967127; called by muse, mutect2, varscan2
- CDK12 | c.1760C>A p.S587Y | Missense Mutation (SNP) | VAF 19/513 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV101420381; called by muse, mutect2
- CELF5 | c.814T>C p.F272L | Missense Mutation (SNP) | VAF 75/168 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV53013435; called by muse, mutect2, varscan2
- CEP290 | c.6473T>C p.L2158S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.225); catalogued as COSV58353970; called by muse, mutect2, varscan2
- CEP89 | c.968A>T p.H323L | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs776618483, COSV59866081; called by muse, mutect2, varscan2
- CIDEA | c.346C>A p.P116T | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as COSV57599643; called by muse, mutect2
- CLEC14A | c.1445A>G p.E482G | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60563506; called by muse, varscan2
- COL12A1 | c.5547C>G p.N1849K | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59401564; called by muse, mutect2, varscan2
- COL21A1 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.052); catalogued as COSV55172244; called by muse, mutect2, varscan2
- CTAGE15 | c.1446A>C p.E482D | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV69482091; called by mutect2, varscan2
- DAND5 | c.35T>G p.L12R | Missense Mutation (SNP) | VAF 45/208 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV57684463; called by muse, mutect2, varscan2
- DCDC1 | c.2033G>T p.S678I | Missense Mutation (SNP) | VAF 10/330 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.576); catalogued as COSV100662845; called by muse, mutect2
- DHCR7 | c.404C>T p.T135I | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62795977; called by muse, mutect2, varscan2
- DIS3L | c.2201+2T>G p.X734_splice (on ENST00000319212 / NM_001143688.3; = p.X651_splice on NM_133375.5 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 39/117 reads (33%) | catalogued as COSV100055618, COSV59913449; called by muse, mutect2, varscan2
- DMD | c.5320G>T p.G1774* | Nonsense Mutation (SNP) | VAF 95/230 reads (41%) | catalogued as COSV63775855; called by muse, mutect2, varscan2
- DNAH3 | c.2916A>C p.E972D | Missense Mutation (SNP) | VAF 229/932 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.022); catalogued as COSV54536700; called by muse, mutect2, varscan2
- EFHB | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 181/415 reads (44%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV55550904; called by muse, mutect2, varscan2
- EGR1 | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 56/71 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53520506; called by muse, varscan2
- ERVFRD-1 | c.221T>G p.I74S | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV65369603; called by muse, mutect2, varscan2
- FAT1 | c.13178C>A p.P4393H | Missense Mutation (SNP) | VAF 261/440 reads (59%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.472); catalogued as COSV71675174; called by muse, mutect2, varscan2
- FCGR1A | c.733T>C p.Y245H | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.466); catalogued as rs1349287179, COSV64985829; called by muse, mutect2, varscan2
- FNDC5 | c.421A>T p.M141L | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.924); catalogued as COSV65105954; called by muse, mutect2, varscan2
- FOLR1 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 227/603 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV56616634, COSV56617250; called by muse, mutect2, varscan2
- FRAS1 | c.3119A>T p.Y1040F | Missense Mutation (SNP) | VAF 231/345 reads (67%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV53629292; called by muse, mutect2, varscan2
- FRMPD3 | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 240/613 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs750463805, COSV52188915; called by muse, mutect2, varscan2
- GAL | c.74G>A p.W25* | Nonsense Mutation (SNP) | VAF 5/10 reads (50%) | catalogued as COSV99681851; called by muse, mutect2, varscan2
- GAPVD1 | c.1619T>G p.L540R | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.526); catalogued as COSV52925435; called by muse, mutect2, varscan2
- GIMAP6 | c.634C>A p.L212M | Missense Mutation (SNP) | VAF 206/684 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); catalogued as rs779061760, COSV61034145; called by muse, mutect2, varscan2
- GNB2 | c.301A>G p.M101V | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV51944673; called by muse, mutect2, varscan2
- GRIP1 | c.2081T>C p.F694S (on ENST00000359742 / NM_001379345.1; = p.F642S on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/498 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as COSV99668379; called by muse, mutect2
- GRM7 | c.366C>A p.F122L | Missense Mutation (SNP) | VAF 80/106 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV63130235, COSV63156217; called by muse, mutect2, varscan2
- HNRNPA1 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); catalogued as COSV52937826; called by muse, mutect2, varscan2
- HSP90AA1 | c.530-2A>T p.X177_splice | Splice Site (SNP) | VAF 13/73 reads (18%) | catalogued as COSV99355085; called by muse, mutect2, varscan2
- IRF2 | c.172T>C p.W58R | Missense Mutation (SNP) | VAF 125/219 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66929998; called by muse, mutect2, varscan2
- ITK | c.1514+1G>A p.X505_splice | Splice Site (SNP) | VAF 81/475 reads (17%) | catalogued as COSV101439655; called by muse, mutect2, varscan2
- KCNQ5 | c.1051G>C p.A351P | Missense Mutation (SNP) | VAF 55/239 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as COSV100573582, COSV59672599; called by muse, mutect2, varscan2
- KIF18B | c.964A>G p.T322A | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59274933; called by muse, mutect2, varscan2
- KNTC1 | c.1616G>T p.W539L | Missense Mutation (SNP) | VAF 45/239 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199501312, COSV61082162; called by muse, mutect2, varscan2
- KRIT1 | c.1738A>G p.N580D | Missense Mutation (SNP) | VAF 101/215 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.226); catalogued as COSV60667081, COSV60669373; called by muse, mutect2, varscan2
- LILRB4 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 88/195 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.171); catalogued as COSV54407036; called by muse, mutect2, varscan2
- LRIF1 | c.2146C>G p.Q716E | Missense Mutation (SNP) | VAF 81/522 reads (16%) | SIFT tolerated (0.82); PolyPhen benign (0.011); catalogued as COSV63897995; called by muse, mutect2, varscan2
- LRP1B | c.12487A>G p.I4163V | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs757814963, COSV101253674; called by muse, mutect2, varscan2
- LRP4 | c.1123dup p.A375Gfs*24 | Frame Shift Ins (INS) | VAF 8/77 reads (10%) | catalogued as rs777522999; called by mutect2, pindel, varscan2
- LRRC7 | c.4205T>A p.V1402E (on ENST00000651989 / NM_001370785.2; = p.V1322E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/199 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV50447427, COSV50521400; called by muse, mutect2, varscan2
- LRRC71 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV61656521; called by muse, mutect2, varscan2
- MAN2A2 | c.928C>G p.L310V | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.433); catalogued as COSV64639136; called by muse, mutect2, varscan2
- MAST2 | c.5397G>C p.*1799Yext*? | Nonstop Mutation (SNP) | VAF 289/369 reads (78%) | catalogued as COSV53109566; called by muse, mutect2, varscan2
- MED12 | c.4524C>G p.H1508Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV61348513; called by muse, mutect2, varscan2
- MED12L | c.2272A>G p.K758E | Missense Mutation (SNP) | VAF 52/355 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV56388033; called by muse, mutect2, varscan2
- MLPH | c.1236G>C p.K412N | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.47); PolyPhen benign (0.106); catalogued as COSV52821728, COSV52822446; called by muse, mutect2, varscan2
- MMP8 | c.875G>T p.R292L | Missense Mutation (SNP) | VAF 161/315 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52633606, COSV52633919; called by muse, mutect2, varscan2
- MSRB1 | c.294C>A p.S98R | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV51907601; called by muse, mutect2, varscan2
- MTO1 | c.734A>G p.K245R | Missense Mutation (SNP) | VAF 93/198 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.33); catalogued as COSV64774428; called by muse, mutect2, varscan2
- MTOR | c.3518C>G p.A1173G | Missense Mutation (SNP) | VAF 170/1233 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV100815790; called by muse, mutect2, varscan2
- MTUS2 | c.2821G>A p.A941T | Missense Mutation (SNP) | VAF 47/60 reads (78%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV70918815; called by muse, mutect2, varscan2
- MYH8 | c.3640C>A p.Q1214K | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV67969167; called by muse, mutect2, varscan2
- MYOM1 | c.4561C>G p.P1521A | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55296651; called by muse, mutect2, varscan2
- NAF1 | c.1119C>G p.F373L | Missense Mutation (SNP) | VAF 91/251 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as COSV56804557, COSV56805149; called by muse, mutect2, varscan2
- NCAN | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs564199075, COSV53054744; called by muse, mutect2, varscan2
- NCKAP1L | c.3047C>G p.S1016C | Missense Mutation (SNP) | VAF 143/350 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.75); catalogued as COSV53209854; called by muse, mutect2, varscan2
- NPC1 | c.2993T>G p.F998C | Missense Mutation (SNP) | VAF 115/279 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV52581277; called by muse, mutect2, varscan2
- NPPB | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 20/67 reads (30%) | catalogued as COSV64687745; called by muse, varscan2
- NUGGC | c.1955A>T p.K652M | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58437161; called by muse, mutect2, varscan2
- OR4C46 | c.581A>T p.E194V | Missense Mutation (SNP) | VAF 79/313 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV60220502; called by muse, mutect2, varscan2
- OR5D16 | c.103G>C p.A35P | Missense Mutation (SNP) | VAF 247/693 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV65721908, COSV65722471; called by muse, mutect2, varscan2
- OTUD4 | c.3115T>G p.S1039A (on ENST00000447906 / NM_001366057.1; = p.S974A on NM_001102653.1) | Missense Mutation (SNP) | VAF 102/403 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV71382075; called by muse, varscan2
- PALM2AKAP2 | c.847A>G p.M283V (on ENST00000374531 / NM_001037293.2; = p.M315V on NM_053016.6) | Missense Mutation (SNP) | VAF 195/359 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV57127206; called by muse, mutect2, varscan2
- PHOX2B | c.20C>A p.S7Y | Missense Mutation (SNP) | VAF 82/120 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56930671; called by muse, mutect2, varscan2
- PKHD1 | c.2134G>C p.V712L | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs144455663, COSV61880538; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEC | c.10316G>T p.R3439M (on ENST00000322810 / NM_201380.4; = p.R3329M on NM_000445.5) | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV59665932; called by muse, mutect2, varscan2
- POGLUT1 | c.639-1G>C p.X213_splice | Splice Site (SNP) | VAF 87/470 reads (19%) | catalogued as COSV55157564; called by muse, mutect2, varscan2
- PREP | c.1016-2A>C p.X339_splice (on ENST00000369110; = p.X405_splice on NM_002726.5) | Splice Site (SNP) | VAF 90/285 reads (32%) | catalogued as COSV64871152; called by muse, mutect2, varscan2
- PSMC3 | c.619A>C p.N207H | Missense Mutation (SNP) | VAF 155/490 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); catalogued as COSV54081863; called by muse, mutect2, varscan2
- PTEN | c.523G>T p.V175L | Missense Mutation (SNP) | VAF 148/320 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV64301465, COSV64302177; called by mutect2, varscan2
- RALGDS | c.295-2A>G p.X99_splice | Splice Site (SNP) | VAF 5/10 reads (50%) | catalogued as COSV64428705; called by muse, mutect2, varscan2
- RBL1 | c.2382G>C p.K794N | Missense Mutation (SNP) | VAF 133/780 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100726844, COSV60331526; called by muse, mutect2, varscan2
- RFXAP | c.598G>T p.E200* | Nonsense Mutation (SNP) | VAF 14/20 reads (70%) | catalogued as rs758466753, COSV55226109; called by muse, mutect2, varscan2
- RHOT1 | c.316G>C p.D106H | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as COSV61717277; called by muse, mutect2, varscan2
- RUFY1 | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV60162224; called by muse, mutect2, varscan2
- SALL1 | c.1730C>A p.P577H | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); catalogued as COSV51761209; called by muse, mutect2, varscan2
- SCN10A | c.4865C>T p.S1622F | Missense Mutation (SNP) | VAF 182/701 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV71861690; called by muse, mutect2, varscan2
- SGSM1 | c.274C>T p.Q92* | Nonsense Mutation (SNP) | VAF 12/80 reads (15%) | catalogued as COSV68511965; called by muse, mutect2, varscan2
- SH2B3 | c.1079C>G p.S360C | Missense Mutation (SNP) | VAF 51/289 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.955); catalogued as COSV57985058; called by muse, mutect2, varscan2
- SLC6A3 | c.1333C>G p.R445G | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM143023, COSV54361620, COSV54366940; called by muse, mutect2, varscan2
- SLC9C1 | c.700A>T p.M234L | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV59890526; called by muse, mutect2, varscan2
- SLIT1 | c.487C>G p.Q163E | Missense Mutation (SNP) | VAF 113/455 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV56594305; called by muse, mutect2, varscan2
- SNAP91 | c.2512G>T p.A838S | Missense Mutation (SNP) | VAF 108/238 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.404); catalogued as COSV52128765; called by muse, mutect2, varscan2
- SS18L1 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV59212061; called by muse, mutect2, varscan2
- STK38L | c.310G>C p.V104L | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV66522360; called by muse, mutect2, varscan2
- TAF5 | c.1543C>G p.L515V | Missense Mutation (SNP) | VAF 66/149 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as COSV60857534; called by muse, mutect2, varscan2
- TBC1D32 | c.3772T>A p.*1258Kext*7 | Nonstop Mutation (SNP) | VAF 88/271 reads (32%) | catalogued as COSV51548824; called by muse, mutect2, varscan2
- TGFBR3 | c.2300G>C p.S767T | Missense Mutation (SNP) | VAF 93/607 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.036); catalogued as COSV53028705, COSV53028718; called by muse, mutect2, varscan2
- TPTE2 | c.147A>C p.E49D | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV55025139; called by muse, mutect2, varscan2
- USP24 | c.7261T>C p.Y2421H | Missense Mutation (SNP) | VAF 59/80 reads (74%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV53773217; called by muse, mutect2, varscan2
- WRN | c.1893T>G p.I631M | Missense Mutation (SNP) | VAF 116/173 reads (67%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV53303946; called by muse, mutect2, varscan2
- Z83844.2 | c.1587G>C p.E529D | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.038); catalogued as COSV53216936; called by muse, mutect2, varscan2
- ZGRF1 | c.4909G>C p.E1637Q | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.122); catalogued as COSV100349292, COSV100349379; called by muse, mutect2
- ZNF197 | c.83C>A p.T28N | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.123); catalogued as COSV60361248; called by muse, mutect2, varscan2
- ZNF236 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 234/351 reads (67%) | catalogued as COSV99469374; called by muse, mutect2, varscan2
- CCDC28A | c.477+1del p.X159_splice | Splice Site (DEL) | VAF 48/151 reads (32%) | called by mutect2, pindel, varscan2
- DDX52 | c.739G>T p.A247S | Missense Mutation (SNP) | VAF 173/249 reads (69%) | SIFT tolerated (0.05); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- KCNIP3 | c.724-11_734del p.X242_splice | Splice Site (DEL) | VAF 22/99 reads (22%) | called by mutect2, pindel
- MAGEE2 | c.1384_1395del p.E462_L465del | In Frame Del (DEL) | VAF 111/272 reads (41%) | called by mutect2, pindel, varscan2
- OR4F5 | c.672T>G p.D224E | Missense Mutation (SNP) | VAF 114/2084 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, varscan2
- OR5T1 | c.569_573del p.F190* | Frame Shift Del (DEL) | VAF 134/939 reads (14%) | called by mutect2, pindel, varscan2
- PIAS1 | c.848_860del p.Y283Cfs*16 | Frame Shift Del (DEL) | VAF 12/154 reads (8%) | called by mutect2, pindel*
- PTPA | c.1030T>C p.F344L (on ENST00000337738 / NM_178001.2; = p.F309L on NM_021131.5) | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.047); called by mutect2, varscan2
- RPF2 | c.477_485del p.K160_L162del | In Frame Del (DEL) | VAF 40/121 reads (33%) | called by mutect2, pindel, varscan2
- SLC6A17 | c.1532_1543del p.F511_R514del | In Frame Del (DEL) | VAF 36/98 reads (37%) | called by mutect2, pindel, varscan2
- SLCO1B3 | c.561del p.I188* | Frame Shift Del (DEL) | VAF 128/418 reads (31%) | called by mutect2, pindel, varscan2
- TBX5 | c.958_974del p.I320Efs*14 | Frame Shift Del (DEL) | VAF 36/242 reads (15%) | called by mutect2, pindel
- TNFAIP3 | c.1368dup p.P457Afs*16 | Frame Shift Ins (INS) | VAF 5/34 reads (15%) | called by pindel, varscan2
- UBN2 | c.1092_1095delinsT p.L365del | In Frame Del (DEL) | VAF 26/132 reads (20%) | called by pindel, varscan2*
- UBR1 | c.4651_4673del p.F1551Gfs*31 | Frame Shift Del (DEL) | VAF 46/283 reads (16%) | called by mutect2, pindel
- ZNF518B | c.3170_3188del p.R1057Lfs*14 | Frame Shift Del (DEL) | VAF 73/120 reads (61%) | called by mutect2, pindel, varscan2
- ANO8 | c.2349C>T p.D783= | Silent (SNP) | VAF 12/121 reads (10%) | catalogued as rs777149212, COSV50188985; called by muse, mutect2, varscan2
- CDK5R1 | c.522C>T p.P174= | Silent (SNP) | VAF 19/26 reads (73%) | catalogued as COSV55577379; called by muse, mutect2, varscan2
- CYP2C9 | c.939G>A p.L313= | Silent (SNP) | VAF 312/727 reads (43%) | catalogued as COSV53250862; called by muse, mutect2, varscan2
- DCAF15 | c.1341A>G p.T447= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs1296557919, COSV54331905; called by muse, mutect2, varscan2
- DCAF5 | c.1455C>A p.P485= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV58461704; called by muse, mutect2, varscan2
- DHX30 | c.1974G>A p.L658= (on ENST00000445061 / NM_138615.3; = p.L619= on NM_014966.3) | Silent (SNP) | VAF 102/233 reads (44%) | catalogued as COSV53140495; called by muse, mutect2, varscan2
- EHD4 | c.399C>T p.N133= | Silent (SNP) | VAF 91/169 reads (54%) | catalogued as rs748481753, COSV55006082; called by muse, mutect2, varscan2
- EPHA6 | c.498A>G p.T166= | Silent (SNP) | VAF 225/648 reads (35%) | catalogued as COSV67583788; called by muse, mutect2, varscan2
- GFRA3 | c.585C>G p.V195= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV51229834; called by muse, mutect2
- GON4L | c.5424G>A p.L1808= | Silent (SNP) | VAF 71/168 reads (42%) | catalogued as rs756975667, COSV55198490; called by muse, mutect2, varscan2
- GPX2 | c.513C>G p.R171= | Silent (SNP) | VAF 151/930 reads (16%) | catalogued as COSV63036521; called by muse, mutect2, varscan2
- LDB3 | c.723C>T p.S241= | Silent (SNP) | VAF 72/225 reads (32%) | catalogued as rs200580597; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRP1B | c.12486G>A p.L4162= | Silent (SNP) | VAF 20/154 reads (13%) | catalogued as COSV101253386, COSV101253676; called by muse, mutect2, varscan2
- LVRN | c.129C>T p.V43= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV63497816; called by muse, mutect2, varscan2
- MAL2 | c.378G>C p.L126= | Silent (SNP) | VAF 39/149 reads (26%) | catalogued as COSV52662126; called by muse, mutect2, varscan2
- MARCO | c.453C>G p.G151= | Silent (SNP) | VAF 208/660 reads (32%) | catalogued as COSV59056464; called by muse, mutect2, varscan2
- MC5R | c.657C>T p.I219= | Silent (SNP) | VAF 88/182 reads (48%) | catalogued as rs747840339, COSV61255214; called by muse, mutect2, varscan2
- NPC1L1 | c.3447C>T p.P1149= | Silent (SNP) | VAF 74/256 reads (29%) | catalogued as COSV56928016; called by muse, mutect2, varscan2
- OR10H4 | c.486G>A p.T162= | Silent (SNP) | VAF 118/270 reads (44%) | catalogued as rs201781055; called by muse, varscan2
- PARP9 | c.99C>A p.I33= | Silent (SNP) | VAF 21/267 reads (8%) | catalogued as rs1191014369, COSV64451314; called by muse, mutect2
- PDE8A | c.363G>A p.L121= | Silent (SNP) | VAF 92/322 reads (29%) | catalogued as COSV59638935; called by muse, mutect2, varscan2
- PFAS | c.399G>A p.P133= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs778367280, COSV58978510; called by muse, mutect2, varscan2
- PGA3 | c.201C>A p.P67= | Silent (SNP) | VAF 129/196 reads (66%) | catalogued as rs527696591, COSV100337369, COSV57711923; called by muse, mutect2, varscan2
- PNPLA6 | c.2571C>T p.D857= (on ENST00000414982 / NM_001166111.2; = p.D809= on NM_006702.5) | Silent (SNP) | VAF 47/187 reads (25%) | catalogued as rs771821425, COSV55381768; called by muse, mutect2, varscan2
- PPFIA2 | c.1821A>T p.G607= | Silent (SNP) | VAF 92/811 reads (11%) | catalogued as COSV61043697; called by muse, mutect2, varscan2
- SLC22A11 | c.327C>T p.D109= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs1451543999, COSV57254265; called by muse, mutect2, varscan2
- TEP1 | c.6222C>T p.G2074= | Silent (SNP) | VAF 11/247 reads (4%) | catalogued as COSV99401799; called by muse, mutect2
- TSGA13 | c.42A>C p.S14= | Silent (SNP) | VAF 52/233 reads (22%) | catalogued as COSV63018983; called by muse, mutect2, varscan2
- ZNF189 | c.921A>G p.Q307= | Silent (SNP) | VAF 229/429 reads (53%) | catalogued as rs1372936047, COSV52276145; called by muse, mutect2, varscan2
- DFFB | c.242-117T>C | Intron (SNP) | VAF 36/109 reads (33%) | catalogued as COSV58861232; called by muse, mutect2, varscan2
- YY1AP1 | c.*1G>A | 3'UTR (SNP) | VAF 136/404 reads (34%) | catalogued as COSV99803553; called by muse, mutect2, varscan2
- ZNF833P | n.1008T>A | RNA (SNP) | VAF 48/163 reads (29%) | called by muse, mutect2, varscan2
